Surgical pathology report (de-identified scan), TCGA case TCGA-VW-A8FI, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Northwestern University, specimen TCGA-VW-A8FI-01A (Primary Tumor).

[page 1 of 2]
Surgery Date.

Final Diagnosis

A and D. Brain, left hemisphere tumor, biopsy and excision:

- Anaplastic astrocytoma, WHO grade III, see comment

B and C. Brain, specimen labeled "deep tumor", biopsy and excision:

- Anaplastic astrocytoma, WHO grade III, see comment

Comment: Histologic sections demonstrate a markedly cellular and atypical astrocytic proliferation with a mitotic rate greater than 6 per 10 high powered fields. There are no areas of necrosis or microvascular proliferation noted. The findings are consistent with an anaplastic astrocytoma, WHO grade III. Immunohistochemical stains for p53, Ki-67, and IDH-1 are performed on block C1. Approximately 50% of the tumor cells are positive for p53, and the proliferation index is approximately 5 to 10%. IDH-1 is negative.

This test was developed and its performance characteristics were determined by the .

. It has not been cleared or approved by the U.S. Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

The positive controls demonstrate appropriate positive staining. The known tissue negative controls were negative.

The non-immune serum control was non-reactive.

(Electronically signed by)

Date Finalized:

ICD-O-3
Astrocytoma, grade III 9401/3
Site ^{C1} Brain, supratentorial NOS
C71.0
① Brain NOS C71.9
JL 4/14/14

I, the Attending Pathologist attest by my signature, that this case has been personally reviewed and examined, microscopically and/or grossly and the diagnosis(es) has been made or confirmed by me.

Clinical Information

The patient is a -year-old male with a clinical diagnosis of left-sided brain tumor undergoing a left craniotomy for tumor resection.

Specimen/Gross Description

A. The specimen is received fresh intraoperatively for consultation from , labeled with the patient's name and designated on the requisition as "brain tumor," and consists of a soft, pink-tan to yellow fragment of tissue measuring 0.6 x 0.5 x 0.3 cm. A smear preparation and frozen section are performed. The intraoperative consultation diagnosis by reads "SUBPIAL GLIOMA AND REACTIVE BRAIN PARENCHYMA." The intraoperative consultation diagnosis is communicated to the operating room at or The remainder of the specimen is entirely submitted as follows:

- 1 - frozen section remnant
- 2 - remainder of specimen

B. The specimen is received fresh intraoperatively for consultation from , labeled with the patient's name and designated on the requisition as "deep tumor," and consists of a soft, mucoid, pink fragment of tissue measuring 0.7 x 0.6 x 0.3 cm. A smear preparation is

[page 2 of 2]
Surgery Date:

performed. The intraoperative consultation diagnosis by _____ reads **"HIGH-GRADE GLIOMA."** The intraoperative consultation diagnosis is communicated to the operating room at _____ on _____. The remainder of the specimen is entirely submitted in a single cassette.

C. The specimen is received fresh, labeled with the patient's name and designated on the requisition as "brain tumor," and consists of 10 pieces of soft, mucoid, pink-tan tissue ranging from 0.5 cm to 1.6 cm in greatest dimension and aggregating to 3.0 x 2.0 x 0.8 cm. There are also two soft, tan-white fragments of tissue measuring 1.9 x 0.6 x 0.3 cm and 1.5 x 0.9 x 0.2 cm. The entire specimen is submitted as follows:

C1 - C3	-	mucoid fragments
C4	-	tan-white fragments

D. The specimen is received fresh, labeled with the patient's name and designated on the requisition as "deep tumor," and consists of three pieces of brain tissue, the largest measuring 3.3 x 3.0 x 1.2 cm and having a recognizable leptomeningeal surface. The two smaller fragments measure 2.9 x 1.3 x 0.7 cm and 1.3 x 1.0 x 0.4 cm and each appear to be soft, tan to brown and possibly necrotic. The 3.3 cm fragment is serially sectioned revealing gray and white matter with blurring of the gray-white junction. Representative sections are submitted in four cassettes.

Intraprocedural Consultation Findings

- A. Subpial glioma and reactive brain parenchyma.
- B. High-grade glioma.

Criteria	11/5/13	Yes	No

Source: NCI Genomic Data Commons file adcf31ef-5e31-4a8c-94cb-a542f59da8ee (TCGA-VW-A8FI.B073A7FE-1986-4EF7-B186-F6017EE50452.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).